Somatic mutation profile of tumor specimen 0DP8OC from CCDI case PBCDFH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.5 years (2,381 days).
Specimen 0DP8OC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60bac800-a95f-42b5-8ff9-7774804aa586.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP8O1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2febb0b9-315e-4fa2-b0f9-ee0850bec2ae

The open-access MAF lists 25 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Intron 2, 3'UTR 1, RNA 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 181/670 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BIRC6 | c.8371G>A p.E2791K | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV70207841; called by muse, mutect2
- CALCR | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 134/766 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs148132671; called by muse, mutect2, varscan2
- CEBPE | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.665); catalogued as rs374190826; called by muse, mutect2, varscan2
- PRMT3 | c.1277C>T p.T426M | Missense Mutation (SNP) | VAF 91/231 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as rs772412108, COSV58180540; called by muse, mutect2, varscan2
- SERPINB12 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 147/189 reads (78%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs948500841; called by muse, mutect2, varscan2
- TTC16 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 147/349 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1014584804; called by muse, mutect2, varscan2
- ZNF790 | c.1762C>A p.L588I | Missense Mutation (SNP) | VAF 24/241 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV63212665; called by muse, mutect2
- ZYG11A | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 215/507 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs994184027, COSV65292290; called by muse, mutect2, varscan2
- BRD4 | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 218/860 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by mutect2, varscan2
- EGLN3 | c.518C>A p.S173* | Nonsense Mutation (SNP) | VAF 232/507 reads (46%) | called by muse, mutect2, varscan2
- FUZ | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 261/614 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 17/507 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- PPM1D | c.1464_1474del p.D488Efs*2 | Frame Shift Del (DEL) | VAF 404/676 reads (60%) | called by mutect2, varscan2
- PWWP3A | c.1849G>A p.E617K (on ENST00000627377; = p.E616K on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/285 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRPA1 | c.2585T>A p.M862K | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRA1 | c.690C>T p.I230= | Silent (SNP) | VAF 103/120 reads (86%) | called by muse, mutect2, varscan2
- CCDC3 | c.753G>A p.A251= | Silent (SNP) | VAF 24/269 reads (9%) | catalogued as rs1321124986, COSV66559212; called by muse, mutect2
- KRT24 | c.1353A>G p.G451= | Silent (SNP) | VAF 224/494 reads (45%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 14/294 reads (5%) | called by muse, mutect2
- ZNF354C | c.190T>C p.L64= | Silent (SNP) | VAF 252/573 reads (44%) | called by muse, mutect2, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 26/192 reads (14%) | called by muse, varscan2
- FIG4 | c.1040-18A>T | Intron (SNP) | VAF 65/138 reads (47%) | called by muse, mutect2, varscan2
- MUC19 | n.7419C>A | RNA (SNP) | VAF 181/408 reads (44%) | called by muse, mutect2, varscan2
- NSD3 | c.2612-45G>A | Intron (SNP) | VAF 6/60 reads (10%) | called by muse, varscan2
